Somatic mutation profile of tumor specimen 0DFHF3 from CCDI case PBBSEE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.7 years (3,896 days).
Specimen 0DFHF3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d573e88-2d81-4859-97e3-b4907186840f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFHF4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5c47013-3be0-4792-8c5f-d2fc6de58c48

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Splice Region 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF3B | c.952A>G p.I318V | Missense Mutation (SNP) | VAF 38/1188 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.04); catalogued as rs1017284863; called by muse, mutect2
- IFI35 | c.120G>A p.K40= | Splice Region (SNP) | VAF 26/610 reads (4%) | called by muse, mutect2
- KLF15 | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 28/654 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.174); called by muse, mutect2
- NRP1 | c.1930C>A p.P644T | Missense Mutation (SNP) | VAF 40/1052 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- SPATA32 | c.790A>G p.M264V | Missense Mutation (SNP) | VAF 18/501 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- SLC25A43 | c.672C>T p.T224= | Silent (SNP) | VAF 37/794 reads (5%) | catalogued as rs142240806; called by muse, mutect2
